Somatic mutation profile of tumor specimen 0DGX3Y from CCDI case PBBUAT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.1 years (1,125 days).
Specimen 0DGX3Y: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eadeccaa-1e7f-4840-a90c-de41af426429.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DGX3W (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93fa1e98-d826-47be-8f9e-f5cdacf66acc

The open-access MAF lists 21 somatic variants for this specimen: 12 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Intron 5, Silent 3, Nonsense Mutation 3, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BTN2A1 | c.455C>A p.S152* | Nonsense Mutation (SNP) | VAF 12/372 reads (3%) | catalogued as COSV57002527; called by muse, mutect2
- KIF13A | c.1139A>T p.Q380L | Missense Mutation (SNP) | VAF 16/307 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.465); catalogued as rs1252217511; called by muse, mutect2
- LAMA2 | c.8918C>T p.T2973M | Missense Mutation (SNP) | VAF 169/345 reads (49%) | SIFT tolerated (0.52); PolyPhen benign (0.031); catalogued as rs145842163, COSV101370335; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LCOR | c.1033C>T p.R345C | Missense Mutation (SNP) | VAF 131/254 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63629887; called by muse, mutect2, varscan2
- RTL1 | c.2459G>A p.R820H | Missense Mutation (SNP) | VAF 102/231 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs1361005947, COSV66017334; called by muse, mutect2, varscan2
- SLAMF7 | c.550T>A p.W184R | Missense Mutation (SNP) | VAF 21/206 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs141021747; called by muse, mutect2, varscan2
- THADA | c.4868C>T p.T1623M | Missense Mutation (SNP) | VAF 165/441 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as rs780984068; called by muse, mutect2, varscan2
- TRIM35 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 114/270 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs752168870; called by muse, mutect2, varscan2
- HNF1A | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 123/279 reads (44%) | called by muse, mutect2, varscan2
- MAN1B1 | c.236C>A p.S79* | Nonsense Mutation (SNP) | VAF 22/422 reads (5%) | called by muse, mutect2
- MBD5 | c.802C>G p.L268V | Missense Mutation (SNP) | VAF 20/357 reads (6%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- PRLR | c.815C>T p.P272L | Missense Mutation (SNP) | VAF 179/434 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNNM3 | c.1839C>T p.P613= | Silent (SNP) | VAF 34/674 reads (5%) | catalogued as rs577439389; called by muse, mutect2
- MRPL18 | c.450G>A p.P150= | Silent (SNP) | VAF 136/296 reads (46%) | catalogued as rs374662908; called by muse, mutect2, varscan2
- OR1N1 | c.816A>T p.A272= | Silent (SNP) | VAF 8/208 reads (4%) | called by muse, mutect2
- ANKRD28 | c.2784-37G>A | Intron (SNP) | VAF 8/100 reads (8%) | called by muse, mutect2
- CBY1 | c.-38-65T>C | Intron (SNP) | VAF 10/112 reads (9%) | called by muse, varscan2
- DENND4B | c.1603+12G>T | Intron (SNP) | VAF 49/496 reads (10%) | called by muse, mutect2
- TUBA1A | c.226+70C>T | Intron (SNP) | VAF 86/155 reads (55%) | catalogued as rs927305574; called by muse, mutect2, varscan2
- VARS1 | c.2418+17G>A | Intron (SNP) | VAF 116/275 reads (42%) | catalogued as rs371885173; called by muse, mutect2, varscan2
- ZFAT | c.*16G>C | 3'UTR (SNP) | VAF 31/216 reads (14%) | called by muse, varscan2
